Somatic mutation profile of cancer-model specimen HCM-BROD-0678-C71-85A (3D Neurosphere, passage 9; aliquot HCM-BROD-0678-C71-85A-01D-A87L-36), derived from the primary tumor of HCMI case HCM-BROD-0678-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Large cell medulloblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 1.2 years (445 days).
Specimen HCM-BROD-0678-C71-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7b0c59ba-38e3-4700-b5cb-41d8715acf17.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0678-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0678-C71-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/704cd591-af57-4618-9e08-5edf22822199

The open-access MAF lists 22 somatic variants for this specimen: 20 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 18, Silent 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CABLES2 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 16/534 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV54157403, COSV54158698; called by muse, mutect2
- NHS | c.3745C>A p.P1249T | Missense Mutation (SNP) | VAF 42/411 reads (10%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.023); catalogued as COSV66280773; called by muse, mutect2
- NOTCH4 | c.5389G>A p.D1797N | Missense Mutation (SNP) | VAF 140/741 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.009); catalogued as rs1311339180; called by muse, mutect2, varscan2
- RABEP2 | c.1328G>A p.R443Q | Missense Mutation (SNP) | VAF 129/660 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.695); catalogued as rs775196829; called by muse, mutect2, varscan2
- RIPOR3 | c.2206C>T p.R736C | Missense Mutation (SNP) | VAF 139/263 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as rs372814425, COSV50396569; called by muse, mutect2, varscan2
- ZDHHC21 | c.634A>G p.I212V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.768); catalogued as rs764229717; called by muse, varscan2
- CGN | c.2515G>T p.E839* | Nonsense Mutation (SNP) | VAF 20/586 reads (3%) | called by muse, mutect2
- FGFR4 | c.2390G>A p.G797E | Missense Mutation (SNP) | VAF 20/668 reads (3%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.336); called by muse, mutect2
- FOXD2 | c.1364T>C p.L455P | Missense Mutation (SNP) | VAF 44/633 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- KRTAP10-1 | c.195C>A p.S65R | Missense Mutation (SNP) | VAF 34/1146 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- KRTAP10-6 | c.953T>G p.V318G | Missense Mutation (SNP) | VAF 282/631 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); called by muse, mutect2
- KRTAP9-7 | c.425C>A p.P142Q | Missense Mutation (SNP) | VAF 39/1253 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2
- MACROH2A1 | c.446C>A p.A149E | Missense Mutation (SNP) | VAF 224/488 reads (46%) | SIFT tolerated (0.28); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- OR52N5 | c.766G>T p.A256S | Missense Mutation (SNP) | VAF 42/670 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); called by muse, mutect2
- SLC4A3 | c.601C>A p.H201N | Missense Mutation (SNP) | VAF 16/468 reads (3%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, mutect2
- TERT | c.1453C>G p.R485G | Missense Mutation (SNP) | VAF 41/606 reads (7%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.672); called by muse, mutect2
- TRIM5 | c.852G>T p.M284I | Missense Mutation (SNP) | VAF 26/414 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.003); called by muse, mutect2
- TRPV2 | c.1321C>A p.L441I | Missense Mutation (SNP) | VAF 19/237 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.059); called by muse, mutect2
- XIRP2 | c.6254C>A p.S2085Y (on ENST00000628543; = p.S2260Y on NM_152381.6) | Missense Mutation (SNP) | VAF 26/511 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); called by muse, mutect2
- YY1 | c.690dup p.D231Rfs*3 | Frame Shift Ins (INS) | VAF 73/180 reads (41%) | called by mutect2, varscan2
- PLCB3 | c.1518G>A p.P506= | Silent (SNP) | VAF 35/443 reads (8%) | catalogued as rs770265455; called by muse, mutect2
- PPBP | c.249C>T p.I83= | Silent (SNP) | VAF 213/436 reads (49%) | catalogued as rs558211014; called by muse, mutect2, varscan2
